Somatic mutation profile of cancer-model specimen HCM-CSHL-0765-C56-85P (3D Organoid, passage 6; aliquot HCM-CSHL-0765-C56-85P-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0765-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary.
Specimen HCM-CSHL-0765-C56-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d21991a-2e48-4db3-85a5-f74735a5ed85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0765-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0765-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/575e79b2-b7e5-4b29-a99b-598b8e8e23ce

The open-access MAF lists 196 somatic variants for this specimen: 141 protein-altering or splice-affecting, 48 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 48, Nonsense Mutation 6, Frame Shift Del 5, Intron 4, In Frame Del 3, 3'UTR 2, Frame Shift Ins 1, In Frame Ins 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 160/181 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4967C>T p.T1656I (on ENST00000272895 / NM_173076.3; = p.T1338I on NM_015657.3) | Missense Mutation (SNP) | VAF 80/128 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781268223; called by muse, mutect2, varscan2
- ADAMTS9 | c.5459C>T p.T1820M | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as rs746487812, COSV55775369; called by muse, mutect2, varscan2
- AFF2 | c.3832G>C p.D1278H | Missense Mutation (SNP) | VAF 109/541 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99661353; called by muse, mutect2, varscan2
- BCAP31 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1420709522; called by muse, mutect2
- C10orf71 | c.3707G>A p.R1236H | Missense Mutation (SNP) | VAF 140/728 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.963); catalogued as rs1032262986, COSV60507216; called by muse, mutect2, varscan2
- CACNA1A | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 74/305 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as rs185034915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD1L | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 39/624 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100787475; called by muse, mutect2
- CNOT6L | c.1025G>A p.G342D (on ENST00000504123 / NM_001286790.2; = p.G337D on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/162 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1349074651; called by muse, mutect2, varscan2
- DNAJB6 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 39/259 reads (15%) | catalogued as rs1302887386, COSV51094310; called by muse, mutect2, varscan2
- DOP1A | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767147189; called by muse, mutect2, varscan2
- DUSP29 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 111/705 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1021479083, COSV58301116; called by muse, mutect2, varscan2
- EDN3 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 92/535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61107187; called by muse, mutect2, varscan2
- EFCAB5 | c.2996T>C p.V999A | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773208910; called by muse, mutect2, varscan2
- EZR | c.798C>G p.D266E | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs749537363; called by muse, mutect2, varscan2
- FAM3A | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 81/718 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1324453425, COSV59194230; called by muse, varscan2
- FER1L6 | c.5259G>A p.W1753* | Nonsense Mutation (SNP) | VAF 55/710 reads (8%) | catalogued as rs200092813; called by muse, mutect2
- FTCD | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 370/558 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs775288681; called by muse, mutect2
- HNF4G | c.343C>T p.R115C (on ENST00000354370 / NM_001330561.2; = p.R162C on NM_004133.5) | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs757866904, COSV62968787; called by muse, mutect2
- IFT140 | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 190/317 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs548992623; called by muse, mutect2, varscan2
- ITPR1 | c.1450G>A p.V484I (on ENST00000354582; = p.V469I on NM_002222.7) | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs752031193; called by muse, mutect2, varscan2
- KCNN1 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 43/488 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs769374870; called by muse, mutect2
- KRTAP9-2 | c.324C>A p.S108R | Missense Mutation (SNP) | VAF 40/607 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs139529894; called by muse, mutect2
- LIMCH1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780080890, COSV58291087; called by muse, mutect2
- LRCH2 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as COSV57759734; called by muse, mutect2, varscan2
- MBD3 | c.111C>T p.S37= | Splice Region (SNP) | VAF 9/259 reads (3%) | catalogued as COSV50084434; called by muse, mutect2
- NID1 | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200467845, COSV51614828; called by muse, mutect2, varscan2
- NRXN1 | c.2536A>T p.N846Y | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58479031; called by muse, mutect2, varscan2
- OLFM3 | c.632G>A p.R211H (on ENST00000338858 / NM_001288821.1; = p.R191H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs776719691, COSV58801848, COSV58804479; called by muse, mutect2, varscan2
- OR5M8 | c.720T>G p.C240W | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59117000; called by muse, mutect2, varscan2
- PCDH11X | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 67/473 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as rs1456284641; called by muse, mutect2, varscan2
- PCDHA13 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 90/569 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1360744073; called by muse, mutect2, varscan2
- PIEZO1 | c.4220T>C p.L1407P | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1196798248; called by muse, mutect2
- PLCL2 | c.2866C>G p.L956V (on ENST00000615277 / NM_001144382.2; = p.L830V on NM_015184.5) | Missense Mutation (SNP) | VAF 176/487 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.188); catalogued as rs759668469; called by muse, mutect2, varscan2
- PORCN | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV58226274; called by muse, mutect2, varscan2
- PSD | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 122/172 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs781256178; called by muse, mutect2, varscan2
- RELN | c.9113G>A p.R3038H | Missense Mutation (SNP) | VAF 102/458 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV59029814; called by muse, mutect2, varscan2
- RESF1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 35/365 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776111676; called by muse, mutect2
- RPGRIP1 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs1051866552; called by muse, mutect2
- SLC44A1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs776010289, COSV66025835; called by muse, mutect2, varscan2
- STARD8 | c.2300del p.S767Cfs*3 | Frame Shift Del (DEL) | VAF 73/394 reads (19%) | catalogued as COSV52923878; called by mutect2, pindel, varscan2
- SVEP1 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238036; called by muse, mutect2, varscan2
- SYP | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 134/432 reads (31%) | catalogued as COSV99603197; called by muse, mutect2, varscan2
- TMEM247 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 117/545 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1326077198; called by muse, mutect2, varscan2
- TRPC3 | c.2057C>T p.T686I (on ENST00000379645 / NM_001366479.2; = p.T613I on NM_003305.2) | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53371922, COSV53378149; called by muse, mutect2, varscan2
- ZDHHC19 | c.187G>C p.V63L | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV56348721; called by muse, mutect2, varscan2
- ZNF329 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs759741486, COSV63773078; called by muse, mutect2, varscan2
- ZNF33A | c.2252A>G p.N751S (on ENST00000458705 / NM_006974.3; = p.N752S on NM_006954.2) | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1473646989; called by muse, mutect2
- ZNF727 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101473409; called by muse, mutect2, varscan2
- ADAMTS2 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALK | c.3221A>G p.Q1074R | Missense Mutation (SNP) | VAF 87/509 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ALOX5 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 211/699 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AMDHD2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 206/598 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ANO1 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 65/513 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP4 | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 65/664 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARHGEF2 | c.379T>C p.S127P (on ENST00000361247 / NM_001162383.2; = p.S100P on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/448 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARIH2 | c.453_455del p.L152del | In Frame Del (DEL) | VAF 95/398 reads (24%) | called by mutect2, pindel, varscan2
- ARPC2 | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 25/313 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2
- ATP11C | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 66/500 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- B3GALT5 | c.848C>G p.A283G | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- BRWD1 | c.5314A>T p.T1772S | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C16orf89 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CADPS2 | c.3388T>A p.F1130I | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CARD10 | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC39 | c.1703T>A p.V568D | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CEP290 | c.3487A>G p.R1163G | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CGB2 | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 32/718 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2
- CXorf56 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 101/744 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DEPDC1 | c.722A>C p.D241A | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DOK3 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 30/636 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- DST | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DZIP1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENTPD6 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 85/574 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- EVPL | c.3887G>A p.G1296D | Missense Mutation (SNP) | VAF 144/894 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); called by muse, mutect2
- FANCD2 | c.4262C>A p.S1421Y | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- FGD4 | c.1014C>G p.S338R | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GABRG2 | c.173C>G p.T58S | Missense Mutation (SNP) | VAF 57/417 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GDF11 | c.1147del p.L383Sfs*100 | Frame Shift Del (DEL) | VAF 90/479 reads (19%) | called by mutect2, pindel, varscan2
- GNPTG | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 154/495 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPAA1 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 31/1205 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- HEPH | c.2232G>T p.W744C (on ENST00000343002; = p.W477C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/503 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS2ST1 | c.137dup p.R47Kfs*8 | Frame Shift Ins (INS) | VAF 58/215 reads (27%) | called by mutect2, pindel, varscan2
- HYDIN | c.14088G>C p.M4696I | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGHA1 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 141/582 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- IRX2 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 40/800 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); called by muse, mutect2
- ITGAD | c.239A>C p.H80P | Missense Mutation (SNP) | VAF 93/395 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNS2 | c.1224G>C p.L408F | Missense Mutation (SNP) | VAF 83/586 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- KLHL25 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KMT2C | c.8981_8990del p.I2994Nfs*35 | Frame Shift Del (DEL) | VAF 50/453 reads (11%) | called by mutect2, pindel, varscan2
- KPNA7 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 94/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP10-8 | c.505A>T p.I169F | Missense Mutation (SNP) | VAF 93/608 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MMP24 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 50/556 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MOS | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MPHOSPH8 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTFP1 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOS1 | c.2639C>A p.A880D | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NUDT10 | c.422_436del p.E141_L145del | In Frame Del (DEL) | VAF 58/225 reads (26%) | called by mutect2, pindel, varscan2
- OR2M4 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR4A8 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.005); called by muse, mutect2
- PCDH15 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PER3 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 121/421 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PNMA1 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 115/409 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PODXL2 | c.1804_1806dup p.D602dup | In Frame Ins (INS) | VAF 98/558 reads (18%) | called by mutect2, pindel, varscan2
- POLH | c.1956C>G p.D652E | Missense Mutation (SNP) | VAF 120/543 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRCP | c.1182_1189del p.C394* | Nonsense Mutation (DEL) | VAF 62/392 reads (16%) | called by mutect2, pindel, varscan2
- RECQL4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 317/1351 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- REELD1 | c.1563C>G p.S521R | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- RFX6 | c.568T>G p.Y190D | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROS1 | c.3502G>C p.D1168H | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RUSC1 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 67/758 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); called by muse, mutect2
- RYR2 | c.12628G>T p.D4210Y | Missense Mutation (SNP) | VAF 88/418 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SAC3D1 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN2A | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); called by muse, mutect2
- SCNN1D | c.385C>A p.P129T (on ENST00000338555; = p.P293T on NM_001130413.4) | Missense Mutation (SNP) | VAF 90/375 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4F | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- SLAMF8 | c.534C>A p.S178R | Missense Mutation (SNP) | VAF 129/554 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SMG1 | c.1503G>C p.L501F | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SOCS6 | c.1367A>T p.D456V | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SOWAHB | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 104/636 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUPT3H | c.560T>A p.I187N (on ENST00000371460 / NM_181356.3; = p.I176N on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYN1 | c.1373A>T p.Q458L | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SYNPO | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 210/635 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYTL5 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- TAF1D | c.548_550del p.G183del | In Frame Del (DEL) | VAF 141/201 reads (70%) | called by mutect2, pindel, varscan2
- TBXAS1 | c.1485C>A p.H495Q | Missense Mutation (SNP) | VAF 127/602 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TCEAL1 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 134/875 reads (15%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRKH | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 96/589 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TIAM2 | c.2448T>A p.F816L | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- TMEM184A | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 44/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TMEM204 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 129/468 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNS3 | c.1915_1925del p.S639Cfs*13 | Frame Shift Del (DEL) | VAF 116/726 reads (16%) | called by mutect2, pindel, varscan2
- TRIM6 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.33052A>T p.K11018* (on ENST00000591111; = p.K10091* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/210 reads (31%) | called by muse, mutect2, varscan2
- TUBB8B | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 130/1015 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- UBE2B | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.7766A>C p.H2589P | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP11 | c.740C>G p.S247* (on ENST00000218348; = p.S204* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 160/379 reads (42%) | called by muse, mutect2, varscan2
- VEZF1 | c.1065_1071del p.H355Qfs*8 | Frame Shift Del (DEL) | VAF 148/336 reads (44%) | called by mutect2, pindel, varscan2
- ZNF311 | c.1156C>G p.P386A | Missense Mutation (SNP) | VAF 130/697 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF568 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ZNF831 | c.4104A>T p.E1368D | Missense Mutation (SNP) | VAF 60/583 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ABCF2 | c.954A>C p.L318= | Silent (SNP) | VAF 57/329 reads (17%) | called by muse, mutect2, varscan2
- AC021072.1 | c.357C>T p.C119= | Silent (SNP) | VAF 131/460 reads (28%) | called by muse, mutect2, varscan2
- AC099489.1 | c.708G>C p.L236= | Silent (SNP) | VAF 35/721 reads (5%) | called by muse, mutect2
- ANKMY2 | c.1131A>G p.Q377= | Silent (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- ANKRD31 | c.270C>T p.S90= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs375356487; called by muse, mutect2, varscan2
- ANKS4B | c.708G>A p.E236= | Silent (SNP) | VAF 76/365 reads (21%) | called by muse, mutect2, varscan2
- ATAD3B | c.792C>T p.G264= (on ENST00000308647; = p.G370= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/369 reads (15%) | catalogued as rs570011887; called by muse, mutect2, varscan2
- B3GALT6 | c.708C>T p.R236= | Silent (SNP) | VAF 233/731 reads (32%) | catalogued as rs533982228; called by muse, mutect2, varscan2
- CDH18 | c.2301T>C p.L767= | Silent (SNP) | VAF 42/361 reads (12%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1782C>T p.I594= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as COSV100664806, COSV100673938, COSV62182560; called by muse, mutect2, varscan2
- DSG4 | c.1230A>G p.T410= | Silent (SNP) | VAF 73/306 reads (24%) | catalogued as COSV57390806; called by muse, mutect2, varscan2
- DST | c.17268T>A p.S5756= (on ENST00000361203 / NM_001374722.1; = p.S3453= on NM_015548.5) | Silent (SNP) | VAF 85/378 reads (22%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.1032G>A p.P344= | Silent (SNP) | VAF 95/425 reads (22%) | catalogued as rs368215241; called by muse, mutect2, varscan2
- GEMIN5 | c.96G>C p.A32= | Silent (SNP) | VAF 157/953 reads (16%) | called by muse, mutect2, varscan2
- GIT1 | c.855C>T p.D285= | Silent (SNP) | VAF 98/234 reads (42%) | catalogued as rs368894186; called by muse, varscan2
- GRWD1 | c.1239C>T p.G413= | Silent (SNP) | VAF 132/463 reads (29%) | catalogued as rs778303240, COSV53518655; called by muse, mutect2, varscan2
- HMGCS2 | c.435C>A p.L145= | Silent (SNP) | VAF 107/928 reads (12%) | catalogued as COSV101024915; called by muse, mutect2, varscan2
- ITGA9 | c.705C>T p.N235= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as rs139839965; called by muse, mutect2, varscan2
- MDN1 | c.6318G>A p.E2106= | Silent (SNP) | VAF 16/203 reads (8%) | called by muse, mutect2
- MFSD6 | c.2322G>A p.P774= | Silent (SNP) | VAF 30/401 reads (7%) | catalogued as rs777729645; called by muse, mutect2
- MID2 | c.825T>G p.T275= | Silent (SNP) | VAF 83/438 reads (19%) | catalogued as COSV53311288; called by muse, mutect2, varscan2
- MMRN2 | c.1633C>T p.L545= | Silent (SNP) | VAF 351/933 reads (38%) | called by muse, mutect2, varscan2
- NEB | c.1749G>C p.L583= | Silent (SNP) | VAF 59/248 reads (24%) | called by muse, mutect2, varscan2
- NPVF | c.285C>T p.N95= | Silent (SNP) | VAF 113/471 reads (24%) | catalogued as rs770081627; called by muse, mutect2, varscan2
- NR1H4 | c.780C>T p.T260= (on ENST00000551379 / NM_001206993.2; = p.T246= on NM_005123.4) | Silent (SNP) | VAF 36/172 reads (21%) | catalogued as rs1322754256; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR5H1 | c.669C>T p.F223= | Silent (SNP) | VAF 81/180 reads (45%) | catalogued as rs766879445, COSV63403360; called by muse, mutect2, varscan2
- PIEZO1 | c.4219C>T p.L1407= | Silent (SNP) | VAF 81/334 reads (24%) | called by muse, mutect2
- PIK3C2A | c.843G>A p.V281= | Silent (SNP) | VAF 80/241 reads (33%) | catalogued as COSV99790187; called by muse, mutect2, varscan2
- PLVAP | c.144C>G p.V48= | Silent (SNP) | VAF 73/656 reads (11%) | called by muse, mutect2, varscan2
- PLXND1 | c.1452G>A p.A484= | Silent (SNP) | VAF 189/559 reads (34%) | catalogued as rs763302268, COSV60711615; called by muse, mutect2, varscan2
- PPARA | c.1251G>A p.P417= | Silent (SNP) | VAF 102/302 reads (34%) | catalogued as rs760285202, COSV53077080; called by muse, mutect2, varscan2
- PTPRF | c.1164C>T p.R388= | Silent (SNP) | VAF 177/572 reads (31%) | catalogued as rs1360187245, COSV63446270; called by muse, mutect2, varscan2
- RAD23A | c.312G>A p.P104= | Silent (SNP) | VAF 50/940 reads (5%) | catalogued as rs369559169; called by muse, mutect2
- RTP1 | c.594C>T p.I198= | Silent (SNP) | VAF 128/783 reads (16%) | catalogued as rs370117897; called by muse, mutect2, varscan2
- SDR9C7 | c.435G>C p.L145= | Silent (SNP) | VAF 32/671 reads (5%) | called by muse, mutect2
- SLC39A10 | c.982C>T p.L328= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV62768452; called by muse, mutect2, varscan2
- SMG7 | c.1281G>A p.L427= | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as rs377000417; called by muse, mutect2, varscan2
- STX16 | c.6C>T p.A2= | Silent (SNP) | VAF 62/374 reads (17%) | called by muse, mutect2, varscan2
- THUMPD3 | c.1440C>T p.Y480= | Silent (SNP) | VAF 115/620 reads (19%) | catalogued as rs770475931, COSV61506236; called by muse, mutect2, varscan2
- TMEM41A | c.222C>T p.C74= | Silent (SNP) | VAF 88/560 reads (16%) | catalogued as rs141827531; called by muse, mutect2, varscan2
- TRHDE | c.492C>T p.S164= | Silent (SNP) | VAF 128/504 reads (25%) | called by muse, varscan2
- TTC12 | c.1824C>T p.S608= | Silent (SNP) | VAF 34/194 reads (18%) | catalogued as rs767317462, COSV59099002; called by muse, mutect2
- TTLL3 | c.279C>T p.L93= | Silent (SNP) | VAF 160/833 reads (19%) | catalogued as rs560428064, COSV55028109; called by muse, mutect2, varscan2
- XAB2 | c.117T>G p.L39= | Silent (SNP) | VAF 114/400 reads (29%) | called by muse, mutect2, varscan2
- ZAN | c.3477C>T p.Y1159= | Silent (SNP) | VAF 87/335 reads (26%) | catalogued as rs1054750227; called by muse, mutect2, varscan2
- ZCCHC7 | c.1014G>A p.P338= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs766478465, COSV60956349; called by muse, mutect2, varscan2
- ZNF250 | c.1518A>G p.P506= | Silent (SNP) | VAF 77/636 reads (12%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.1042T>C p.L348= | Silent (SNP) | VAF 60/278 reads (22%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3372G>T | Intron (SNP) | VAF 38/1320 reads (3%) | called by muse, mutect2
- C6orf136 | c.72+53C>T | Intron (SNP) | VAF 229/985 reads (23%) | catalogued as rs780504031; called by muse, mutect2, varscan2
- DCHS2 | n.1282C>T | RNA (SNP) | VAF 187/218 reads (86%) | catalogued as COSV59719307; called by muse, mutect2, varscan2
- MAPK9 | c.688+9C>T | Intron (SNP) | VAF 100/370 reads (27%) | catalogued as rs758019397; called by muse, mutect2
- PHF8 | c.*1128G>A | 3'UTR (SNP) | VAF 119/301 reads (40%) | called by muse, mutect2, varscan2
- RCAN2 | c.*1188G>A | 3'UTR (SNP) | VAF 74/374 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.34264+5293G>A | Intron (SNP) | VAF 24/300 reads (8%) | catalogued as rs1209026573, COSV60114890, COSV60160537; ClinVar: likely benign; called by muse, mutect2
